Somatic mutation profile of tumor specimen MMRF_1506_1_BM_CD138pos (aliquot MMRF_1506_1_BM_CD138pos_T1_KBS5U_L02997) from MMRF case MMRF_1506, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.6 years (19,954 days).
Specimen MMRF_1506_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e2dd3bf-bb31-4842-a33d-0175ad00a328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1506_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1506_1_PB_Whole_C3_KBS5U_L03005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d411d52-006c-4e90-b9d3-f8718cce150f

The open-access MAF lists 90 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 15, Intron 10, Silent 10, RNA 4, Nonsense Mutation 3, Frame Shift Del 2, 5'Flank 2, 5'UTR 2, 3'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 62/171 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs932852974; called by muse, mutect2, varscan2
- ANKRD9 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs1390440184; called by muse, mutect2, varscan2
- ARHGAP25 | c.1353G>T p.L451F (on ENST00000409202 / NM_001007231.3; = p.L443F on NM_014882.3) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV54900524; called by muse, mutect2
- BLK | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs777278971; called by muse, mutect2, varscan2
- BTBD11 | c.2890G>A p.E964K (on ENST00000280758 / NM_001018072.2; = p.E501K on NM_001017523.2) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99776732; called by muse, mutect2, varscan2
- DCAF12L1 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64421963, COSV64422100; called by muse, mutect2, varscan2
- DOCK6 | c.3013C>A p.L1005M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs759337643, COSV53919917; called by muse, mutect2, varscan2
- ELP2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 109/113 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370904237; called by muse, mutect2, varscan2
- GRM6 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs369887161; called by muse, mutect2, varscan2
- IGHV2-70 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs61997764; called by muse, varscan2
- IGHV3-21 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.861); catalogued as rs782444127; called by muse, mutect2, varscan2
- KRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2
- LANCL1 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs748813502; called by muse, mutect2, varscan2
- SLC2A10 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs774991993, COSV63714462; called by muse, mutect2, varscan2
- TAFA1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs758404527; called by muse, mutect2, varscan2
- YTHDF2 | c.1443_1444del p.A483Rfs*13 | Frame Shift Del (DEL) | VAF 30/43 reads (70%) | catalogued as rs1557541400, COSV65723017; called by mutect2, pindel, varscan2
- ZNF502 | c.1530C>A p.Y510* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as COSV56075377; called by muse, mutect2, varscan2
- ADAM19 | c.1378T>G p.S460A | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.81); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C1orf198 | c.884A>T p.D295V | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CCDC96 | c.720C>G p.N240K | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DPYSL4 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ECPAS | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EEF2 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ERBIN | c.4118A>G p.D1373G (on ENST00000284037 / NM_001253697.2; = p.D1332G on NM_018695.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRXCR2 | c.638del p.G213Afs*18 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- GSTK1 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- IPO11 | c.2813A>T p.Y938F | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- LRP1B | c.671T>G p.M224R | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRD1 | c.793G>C p.G265R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- MYO15A | c.4861T>A p.F1621I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO15A | c.7117+3C>T | Splice Region (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- NCKAP5 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR5A1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- NSMF | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R12A | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RASA3 | c.198C>A p.Y66* | Nonsense Mutation (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2, varscan2
- RUNDC3B | c.23dup p.L9Pfs*41 | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- RWDD2B | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SIPA1L1 | c.2920G>T p.V974L | Missense Mutation (SNP) | VAF 72/73 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TMEFF1 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.097); called by mutect2, varscan2
- UBE3C | c.2078T>A p.V693D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- WDR72 | c.1146T>A p.D382E | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFAT | c.2129C>G p.S710* | Nonsense Mutation (SNP) | VAF 38/68 reads (56%) | called by muse, mutect2, varscan2
- ZNF358 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ZNF573 | c.1879C>G p.Q627E (on ENST00000536220 / NM_001172692.1; = p.Q569E on NM_152360.3) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- COL6A2 | c.870C>T p.I290= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs775046253; called by muse, mutect2, varscan2
- CSAG1 | c.54G>T p.R18= | Silent (SNP) | VAF 36/37 reads (97%) | called by muse, mutect2, varscan2
- DMAC2 | c.396T>G p.G132= | Silent (SNP) | VAF 72/139 reads (52%) | called by muse, mutect2, varscan2
- DOCK11 | c.1470A>G p.T490= | Silent (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- DOCK4 | c.2439C>A p.G813= | Silent (SNP) | VAF 63/144 reads (44%) | called by muse, mutect2, varscan2
- FAT2 | c.8176C>T p.L2726= | Silent (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- FBN3 | c.6243C>T p.S2081= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- TH | c.441G>A p.R147= (on ENST00000381178 / NM_199292.3; = p.R116= on NM_000360.4) | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- TPCN2 | c.315C>T p.L105= | Silent (SNP) | VAF 117/234 reads (50%) | catalogued as rs1305231887; called by muse, mutect2, varscan2
- ZC3H12C | c.1410T>A p.V470= | Silent (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- AARS2 | c.*737G>A | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- AGTR2 | c.*1406A>G | 3'UTR (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- ANO1 | c.1951-52G>T | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- AP001496.2 | n.773C>A | RNA (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2
- ATG16L2 | c.887+47C>T | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- DALRD3 | chr3:49021071 C>A | 5'Flank (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- DDX5 | c.44+172G>C | Intron (SNP) | VAF 65/140 reads (46%) | called by muse, mutect2, varscan2
- DGKB | c.-39T>G | 5'UTR (SNP) | VAF 101/216 reads (47%) | called by muse, mutect2, varscan2
- EIF1 | c.*403G>A | 3'UTR (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- FRA10AC1 | c.*1580T>A | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- GAS7 | c.184-97G>A | Intron (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- GATAD2A | c.*3189A>G | 3'UTR (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- GPR1 | c.*234G>C | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- HTRA2 | c.906+100G>A | Intron (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- IMPG1 | c.*676C>A | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- KLHL13 | c.*989G>T | 3'UTR (SNP) | VAF 19/19 reads (100%) | called by muse, mutect2, varscan2
- LARP1B | c.988+1365G>C | Intron (SNP) | VAF 29/30 reads (97%) | called by muse, mutect2, varscan2
- MACROD2 | c.164-33777dup | Intron (INS) | VAF 7/16 reads (44%) | called by mutect2, pindel, varscan2
- MIR212 | n.17G>A | RNA (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- NAP1L6P | n.1241A>T | RNA (SNP) | VAF 50/52 reads (96%) | called by muse, mutect2, varscan2
- NAP1L6P | n.1240G>T | RNA (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- NDUFAF3 | chr3:49021383 G>C | 5'Flank (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- NSD1 | c.927+1168A>G | Intron (SNP) | VAF 28/36 reads (78%) | called by muse, mutect2
- NXPH3 | c.*3049C>T | 3'UTR (SNP) | VAF 47/110 reads (43%) | called by muse, mutect2, varscan2
- OPCML | c.*2119A>C | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- PHLDB1 | c.*128A>C | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- PIAS1 | c.*5151A>C | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- POLR2B | c.-86C>T | 5'UTR (SNP) | VAF 39/40 reads (98%) | called by muse, mutect2, varscan2
- PPP2R2C | c.*580A>G | 3'UTR (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- PYROXD1 | c.*959A>G | 3'UTR (SNP) | VAF 3/17 reads (18%) | catalogued as rs1173559312; called by muse, mutect2
- SH2D3A | c.1272+10dup | Intron (INS) | VAF 55/128 reads (43%) | called by mutect2, pindel, varscan2
- TMEM266 | c.*306C>G | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- ZC4H2 | c.399-59G>T | Intron (SNP) | VAF 29/39 reads (74%) | called by muse, mutect2, varscan2
- ZNF721 | chr4:438596 T>A | 3'Flank (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
